Somatic mutation profile of tumor specimen 0DZU05 from CCDI case PBCTYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 14.9 years (5,426 days).
Specimen 0DZU05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5be04332-7927-4a45-a7e7-54be9ecff600.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZU0W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b6ddfdf-4e14-486f-9f69-b7e42ccecfac

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPEG | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs967635135; called by muse, mutect2
